Somatic mutation profile of cancer-model specimen HCM-BROD-0102-C71-85B (3D Neurosphere, passage 2; aliquot HCM-BROD-0102-C71-85B-01D-A80U-36), derived from the recurrence tumor of HCMI case HCM-BROD-0102-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.2 years (25,280 days).
Specimen HCM-BROD-0102-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 2.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d6f7084-ae6b-4d16-93f3-3d6b81907711.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0102-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0102-C71-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0213d025-bb04-4c6b-a616-ff22f12a92c9

The open-access MAF lists 192 somatic variants for this specimen: 141 protein-altering or splice-affecting, 45 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 114, Silent 45, Frame Shift Del 11, Nonsense Mutation 5, Intron 4, Splice Region 4, In Frame Del 3, Splice Site 3, 5'UTR 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATL1 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 141/288 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as rs119476046, CM013290, COSV63296065; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 161/363 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMDEC1 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 187/383 reads (49%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs763617875, COSV56477440; called by muse, mutect2, varscan2
- AKAP4 | c.2494C>T p.R832W | Missense Mutation (SNP) | VAF 308/580 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as rs140842418; called by muse, mutect2, varscan2
- B9D2 | c.254G>A p.S85N | Missense Mutation (SNP) | VAF 94/256 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as rs771723454, COSV54683738; called by muse, mutect2, varscan2
- BCL11B | c.2305G>A p.G769S (on ENST00000357195 / NM_001282237.2; = p.G698S on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 308/621 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs1237612814; called by muse, mutect2, varscan2
- CAPZA1 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 78/397 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs1457638669, COSV99583422; called by muse, mutect2, varscan2
- CASP5 | c.1015T>C p.S339P | Missense Mutation (SNP) | VAF 166/343 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as rs1178157480; called by muse, mutect2, varscan2
- CCSER1 | c.1786C>T p.R596* | Nonsense Mutation (SNP) | VAF 88/264 reads (33%) | catalogued as rs775072687; called by muse, mutect2, varscan2
- CD209 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 170/305 reads (56%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs368570264; called by muse, mutect2, varscan2
- COL22A1 | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 204/316 reads (65%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs371698463; called by muse, mutect2, varscan2
- COL2A1 | c.1498G>A p.V500I | Missense Mutation (SNP) | VAF 221/482 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs768110640, COSV100476865; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP20A1 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as rs142789807, COSV100619061; called by muse, mutect2, varscan2
- CYSLTR2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 175/386 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201503697; called by muse, mutect2, varscan2
- DCAF8L1 | c.1658G>A p.R553H | Missense Mutation (SNP) | VAF 264/578 reads (46%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as rs772839233, COSV71595169; called by muse, mutect2, varscan2
- DDX5 | c.440_441+2del p.X147_splice | Splice Site (DEL) | VAF 111/265 reads (42%) | catalogued as rs782442161; called by mutect2, pindel, varscan2
- F11 | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 150/280 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs1037131052, CM076173, COSV53002544; called by muse, mutect2
- FAM9B | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 94/241 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV59119436; called by muse, mutect2, varscan2
- FAM9B | c.216G>T p.M72I | Missense Mutation (SNP) | VAF 85/218 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.322); catalogued as rs760665917, COSV59119968; called by mutect2, varscan2
- FBLN2 | c.3416C>T p.T1139M | Missense Mutation (SNP) | VAF 254/504 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768351865; called by muse, mutect2, varscan2
- GNAT3 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 90/342 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775635099, COSV68069429; called by muse, mutect2, varscan2
- HCN1 | c.1972T>A p.S658T | Missense Mutation (SNP) | VAF 243/433 reads (56%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV57506267; called by muse, mutect2, varscan2
- HMCN1 | c.10981C>T p.R3661W | Missense Mutation (SNP) | VAF 110/224 reads (49%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.863); catalogued as rs770186866; called by muse, mutect2, varscan2
- IFIT1 | c.673del p.L225* | Frame Shift Del (DEL) | VAF 151/214 reads (71%) | catalogued as COSV65661341; called by mutect2, pindel, varscan2
- LILRA1 | c.1360C>A p.P454T | Missense Mutation (SNP) | VAF 144/233 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as rs1446141489; called by muse, mutect2, varscan2
- LRRK1 | c.2941G>A p.A981T | Missense Mutation (SNP) | VAF 80/272 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs939724696, COSV52601592, COSV52606441; called by muse, mutect2, varscan2
- MAN2A2 | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 111/321 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs533695393, COSV64637106; called by muse, mutect2, varscan2
- MAP2K5 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 141/333 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51619143; called by muse, mutect2, varscan2
- MATN4 | c.1324C>T p.R442C (on ENST00000372754; = p.R401C on NM_003833.4) | Missense Mutation (SNP) | VAF 172/731 reads (24%) | PolyPhen probably damaging (0.953); catalogued as rs750693265, COSV61350352; called by muse, mutect2, varscan2
- MMRN1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs770818591; called by muse, mutect2
- MRPL36 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 194/330 reads (59%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.446); catalogued as rs146493666; called by muse, mutect2, varscan2
- MYLK | c.3902G>A p.R1301H | Missense Mutation (SNP) | VAF 243/505 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs770980369, COSV100658752; called by muse, mutect2, varscan2
- NEK4 | c.1858C>T p.R620* | Nonsense Mutation (SNP) | VAF 155/353 reads (44%) | catalogued as rs775049834, COSV51780336; called by muse, mutect2, varscan2
- NNT | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 37/287 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759070764; called by muse, mutect2, varscan2
- NUBPL | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 80/223 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as rs1179905165; called by muse, mutect2, varscan2
- OR2AP1 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 98/311 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.814); catalogued as rs761988263; called by muse, mutect2, varscan2
- OR2W3 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 185/185 reads (100%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.783); catalogued as rs866274202, COSV64456921; called by muse, mutect2, varscan2
- P2RY4 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 28/674 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.05); catalogued as rs1159824939, COSV65736388; called by muse, mutect2
- PCDHA8 | c.1243C>G p.R415G | Missense Mutation (SNP) | VAF 166/384 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs781893579, COSV65339333; called by muse, mutect2, varscan2
- RNF17 | c.2244C>T p.I748= | Splice Region (SNP) | VAF 108/211 reads (51%) | catalogued as rs756925498, COSV55034577; called by muse, mutect2, varscan2
- SCAP | c.3703_3706del p.T1235Sfs*? | Frame Shift Del (DEL) | VAF 156/337 reads (46%) | catalogued as rs746678809; called by pindel, varscan2
- SLC4A1 | c.2185G>A p.V729M | Missense Mutation (SNP) | VAF 356/683 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775748758, COSV52262400, COSV52263082; called by muse, mutect2, varscan2
- SLC8A3 | c.2191G>A p.V731I (on ENST00000381269 / NM_183002.3; = p.V729I on NM_033262.4) | Missense Mutation (SNP) | VAF 80/504 reads (16%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.949); catalogued as rs751057430, COSV53688182; called by muse, mutect2, varscan2
- SPATA31A1 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 148/484 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1190727151; called by muse, mutect2, varscan2
- SRRM2 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 139/357 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs376429363; called by muse, mutect2, varscan2
- SSTR3 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 40/676 reads (6%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.464); catalogued as rs367840725; called by muse, mutect2
- STAG2 | c.34A>T p.N12Y | Missense Mutation (SNP) | VAF 15/279 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV54358375; called by muse, mutect2
- TBC1D3F | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 47/256 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs1203682699; called by muse, mutect2, varscan2
- TENM1 | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 32/826 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV64435528; called by muse, mutect2
- TIAM2 | c.701G>T p.R234L | Missense Mutation (SNP) | VAF 130/356 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV59699186; called by muse, mutect2, varscan2
- TTN | c.67564C>T p.R22522C (on ENST00000591111; = p.R15098C on NM_003319.4) | Missense Mutation (SNP) | VAF 198/350 reads (57%) | PolyPhen probably damaging (0.917); catalogued as rs778284888; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.61182A>T p.K20394N (on ENST00000591111; = p.K12970N on NM_003319.4) | Missense Mutation (SNP) | VAF 179/273 reads (66%) | PolyPhen probably damaging (0.923); catalogued as rs373681189; ClinVar: uncertain significance; called by mutect2, varscan2
- VASN | c.350A>G p.N117S | Missense Mutation (SNP) | VAF 202/560 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as rs1288526677, COSV52027934; called by muse, mutect2, varscan2
- VCAN | c.524T>C p.V175A | Missense Mutation (SNP) | VAF 37/376 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs747879341; called by muse, mutect2
- ZNF619 | c.572_574del p.G191del | In Frame Del (DEL) | VAF 134/313 reads (43%) | catalogued as rs767350974; called by pindel, varscan2
- ABCD2 | c.1019A>G p.Y340C | Missense Mutation (SNP) | VAF 40/388 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- AC245033.1 | c.1723A>G p.M575V | Missense Mutation (SNP) | VAF 221/333 reads (66%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADAMTS9 | c.5696T>C p.V1899A | Missense Mutation (SNP) | VAF 21/385 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.034); called by muse, mutect2
- ADGRA3 | c.1813A>G p.T605A | Missense Mutation (SNP) | VAF 76/141 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- ADH5 | c.761T>A p.L254H | Missense Mutation (SNP) | VAF 211/321 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AMER1 | c.2729A>T p.H910L | Missense Mutation (SNP) | VAF 296/620 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ANGPTL5 | c.726G>C p.M242I | Missense Mutation (SNP) | VAF 146/347 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.033); called by muse, mutect2
- ARMH4 | c.1877A>G p.E626G | Missense Mutation (SNP) | VAF 177/434 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ASTN1 | c.3581A>G p.H1194R | Missense Mutation (SNP) | VAF 178/377 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATMIN | c.1540T>C p.C514R | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- ATP11B | c.2098A>G p.I700V | Missense Mutation (SNP) | VAF 17/315 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); called by muse, mutect2
- ATRNL1 | c.3665C>A p.S1222* | Nonsense Mutation (SNP) | VAF 146/147 reads (99%) | called by muse, mutect2, varscan2
- ATRX | c.6541A>T p.T2181S | Missense Mutation (SNP) | VAF 18/517 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); called by muse, mutect2
- BICRA | c.3776T>C p.V1259A | Missense Mutation (SNP) | VAF 138/439 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- BRWD3 | c.4779dup p.E1594Rfs*23 | Frame Shift Ins (INS) | VAF 185/486 reads (38%) | called by mutect2, pindel, varscan2
- C1orf112 | c.1350T>A p.N450K | Missense Mutation (SNP) | VAF 187/377 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- C3 | c.917T>C p.V306A | Missense Mutation (SNP) | VAF 228/366 reads (62%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC177 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 333/656 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- CCDC87 | c.2077G>A p.V693I | Missense Mutation (SNP) | VAF 226/479 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CFAP47 | c.9502A>T p.K3168* | Nonsense Mutation (SNP) | VAF 172/369 reads (47%) | called by muse, mutect2, varscan2
- CFHR4 | c.152A>G p.Y51C (on ENST00000367416 / NM_001201551.2; = p.Y52C on NM_006684.5) | Missense Mutation (SNP) | VAF 34/335 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CHD8 | c.1918G>T p.D640Y (on ENST00000646647 / NM_001170629.2; = p.D361Y on NM_020920.4) | Missense Mutation (SNP) | VAF 140/350 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CHMP4C | c.166A>G p.K56E | Missense Mutation (SNP) | VAF 17/264 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.547); called by muse, mutect2
- CHST15 | c.1117C>G p.L373V | Missense Mutation (SNP) | VAF 10/247 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); called by muse, mutect2
- CSMD1 | c.10328G>T p.G3443V (on ENST00000520002; = p.G3442V on NM_033225.6) | Missense Mutation (SNP) | VAF 101/221 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DAPK1 | c.-107A>G | Splice Region (SNP) | VAF 126/435 reads (29%) | called by muse, mutect2, varscan2
- DNAJC11 | c.485T>C p.M162T | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EFNB1 | c.129G>A p.K43= | Splice Region (SNP) | VAF 207/412 reads (50%) | called by muse, mutect2, varscan2
- ERC2 | c.157_170del p.N53Yfs*9 | Frame Shift Del (DEL) | VAF 202/497 reads (41%) | called by mutect2, pindel, varscan2
- FAM184B | c.1439A>G p.E480G | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2
- FBXW10 | c.1067T>G p.V356G | Missense Mutation (SNP) | VAF 171/348 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- FNDC4 | c.166A>G p.T56A | Missense Mutation (SNP) | VAF 24/524 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.905); called by muse, mutect2
- GAB1 | c.1001T>C p.L334P | Missense Mutation (SNP) | VAF 80/291 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GOLGA6L6 | c.1396T>G p.W466G | Missense Mutation (SNP) | VAF 90/358 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- GPR139 | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 220/351 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIK3 | c.2596A>G p.I866V | Missense Mutation (SNP) | VAF 23/378 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2
- HECTD2 | c.2273A>G p.D758G | Missense Mutation (SNP) | VAF 14/241 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.072); called by muse, mutect2
- HTR1B | c.80C>G p.S27C | Missense Mutation (SNP) | VAF 46/322 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- INA | c.835A>G p.N279D | Missense Mutation (SNP) | VAF 219/256 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IPO13 | c.2156A>G p.D719G | Missense Mutation (SNP) | VAF 69/487 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- KBTBD13 | c.1098C>A p.H366Q | Missense Mutation (SNP) | VAF 213/657 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KIAA1755 | c.1217A>G p.N406S | Missense Mutation (SNP) | VAF 34/542 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- KIF4A | c.3437C>A p.T1146N | Missense Mutation (SNP) | VAF 26/508 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.383); called by muse, mutect2
- KRT81 | c.1429A>C p.T477P | Missense Mutation (SNP) | VAF 132/370 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- LARS1 | c.435T>C p.S145= (on ENST00000394434 / NM_020117.11; = p.S118= on NM_016460.3) | Splice Region (SNP) | VAF 79/152 reads (52%) | called by muse, mutect2, varscan2
- MBNL3 | c.739C>G p.H247D | Missense Mutation (SNP) | VAF 20/464 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); called by muse, mutect2
- MTO1 | c.1854C>G p.F618L (on ENST00000370300 / NM_133645.3; = p.F593L on NM_012123.4) | Missense Mutation (SNP) | VAF 115/196 reads (59%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH6 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 267/551 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- NADK | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 12/323 reads (4%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); called by muse, mutect2
- NALCN | c.701A>G p.E234G | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, varscan2
- NRF1 | c.1320_1325del p.A441_L442del | In Frame Del (DEL) | VAF 48/342 reads (14%) | called by mutect2, pindel, varscan2
- OR8D2 | c.446A>G p.Y149C | Missense Mutation (SNP) | VAF 55/337 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- OVCH1 | c.64+1G>A p.X22_splice | Splice Site (SNP) | VAF 185/382 reads (48%) | called by muse, mutect2, varscan2
- PAOX | c.850_852del p.I284del | In Frame Del (DEL) | VAF 164/175 reads (94%) | called by mutect2, pindel, varscan2
- PCDHGA1 | c.1306A>G p.T436A | Missense Mutation (SNP) | VAF 34/412 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.02); called by muse, mutect2
- PCNT | c.8790_8805del p.K2930Nfs*4 | Frame Shift Del (DEL) | VAF 56/256 reads (22%) | called by mutect2, pindel, varscan2
- PFKP | c.2226-1G>C p.X742_splice | Splice Site (SNP) | VAF 27/75 reads (36%) | called by muse, mutect2, varscan2
- PRG3 | c.596C>A p.S199Y | Missense Mutation (SNP) | VAF 226/414 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PROSER2 | c.891_901del p.A298Rfs*26 | Frame Shift Del (DEL) | VAF 271/283 reads (96%) | called by mutect2, pindel, varscan2
- PTPRF | c.1006A>G p.T336A | Missense Mutation (SNP) | VAF 14/415 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- RAD54B | c.116del p.P39Qfs*3 | Frame Shift Del (DEL) | VAF 63/157 reads (40%) | called by mutect2, pindel, varscan2
- RASSF6 | c.805T>A p.F269I (on ENST00000342081 / NM_201431.2; = p.F237I on NM_177532.5) | Missense Mutation (SNP) | VAF 118/228 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); called by muse, mutect2
- RCBTB2 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 68/250 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIPK2 | c.444G>T p.K148N | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETD2 | c.6940C>T p.Q2314* | Nonsense Mutation (SNP) | VAF 104/233 reads (45%) | called by muse, mutect2, varscan2
- SIGLECL1 | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 183/267 reads (69%) | SIFT tolerated (0.4); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SLC2A9 | c.488C>A p.A163D | Missense Mutation (SNP) | VAF 13/345 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2
- SLC5A7 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 52/354 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO5A1 | c.180_186del p.F61Vfs*10 | Frame Shift Del (DEL) | VAF 153/412 reads (37%) | called by mutect2, pindel, varscan2
- SMPD3 | c.254G>T p.W85L | Missense Mutation (SNP) | VAF 15/452 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SMPDL3B | c.346A>G p.T116A | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- SUSD2 | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 62/253 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- SYNE1 | c.13593del p.V4532Cfs*26 (on ENST00000367255 / NM_182961.4; = p.V4461Cfs*26 on NM_033071.3) | Frame Shift Del (DEL) | VAF 26/225 reads (12%) | called by mutect2, pindel, varscan2
- TET1 | c.1728del p.Y576* | Frame Shift Del (DEL) | VAF 229/318 reads (72%) | called by mutect2, pindel, varscan2
- TIPRL | c.638_639del p.E213Vfs*10 | Frame Shift Del (DEL) | VAF 147/333 reads (44%) | called by mutect2, pindel, varscan2
- USP38 | c.3016T>C p.S1006P | Missense Mutation (SNP) | VAF 47/291 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- USP53 | c.1639A>G p.T547A | Missense Mutation (SNP) | VAF 69/250 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VAV1 | c.2476T>G p.Y826D | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- WFDC5 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 25/874 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- YTHDC1 | c.86A>G p.E29G | Missense Mutation (SNP) | VAF 98/164 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- YY1AP1 | c.1588C>T p.P530S (on ENST00000295566 / NM_139118.2; = p.P473S on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 199/430 reads (46%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZDHHC11 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 9/424 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF140 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 17/331 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0.006); called by muse, mutect2
- ZNF362 | c.1150A>G p.T384A | Missense Mutation (SNP) | VAF 47/318 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZNF394 | c.1522C>A p.Q508K | Missense Mutation (SNP) | VAF 77/729 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- ZNF473 | c.1380del p.K460Nfs*15 | Frame Shift Del (DEL) | VAF 113/373 reads (30%) | called by mutect2, pindel, varscan2
- ADAMTS2 | c.405C>T p.A135= | Silent (SNP) | VAF 107/666 reads (16%) | catalogued as rs749177926; called by muse, mutect2, varscan2
- ADGB | c.3072T>C p.Y1024= | Silent (SNP) | VAF 41/221 reads (19%) | called by muse, mutect2, varscan2
- ANK2 | c.7140G>A p.K2380= | Silent (SNP) | VAF 124/326 reads (38%) | called by muse, mutect2, varscan2
- ANKRD11 | c.6525C>T p.N2175= | Silent (SNP) | VAF 121/351 reads (34%) | called by muse, mutect2, varscan2
- AR | c.1386C>T p.G462= | Silent (SNP) | VAF 68/138 reads (49%) | catalogued as rs773864324; called by muse, varscan2
- ATP12A | c.1782G>A p.P594= | Silent (SNP) | VAF 200/404 reads (50%) | catalogued as rs1452581735, COSV54513773; called by muse, mutect2
- BDP1 | c.1011T>C p.I337= | Silent (SNP) | VAF 12/280 reads (4%) | called by muse, mutect2
- CARD11 | c.2808C>T p.D936= | Silent (SNP) | VAF 122/716 reads (17%) | catalogued as rs375569843; called by muse, mutect2, varscan2
- CCDC185 | c.369G>A p.P123= | Silent (SNP) | VAF 413/786 reads (53%) | catalogued as rs757264824; called by muse, mutect2, varscan2
- CCDC185 | c.984C>A p.R328= | Silent (SNP) | VAF 65/604 reads (11%) | called by muse, mutect2
- CLSTN2 | c.1581C>A p.G527= | Silent (SNP) | VAF 17/497 reads (3%) | catalogued as rs1223255081, COSV71720771; called by muse, mutect2
- FBN3 | c.4746G>A p.T1582= | Silent (SNP) | VAF 107/269 reads (40%) | catalogued as rs201012994, COSV54460044; called by muse, mutect2, varscan2
- FBN3 | c.4341C>T p.N1447= | Silent (SNP) | VAF 82/211 reads (39%) | catalogued as rs767187366; called by muse, mutect2, varscan2
- FUBP1 | c.102A>G p.A34= | Silent (SNP) | VAF 88/490 reads (18%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.1758T>A p.A586= | Silent (SNP) | VAF 206/934 reads (22%) | called by muse, varscan2
- HSD17B10 | c.78G>A p.T26= | Silent (SNP) | VAF 115/681 reads (17%) | called by muse, mutect2, varscan2
- IL1B | c.195G>A p.A65= | Silent (SNP) | VAF 193/304 reads (63%) | catalogued as rs780676196, COSV54522250; called by muse, mutect2, varscan2
- INPP5F | c.1665T>C p.D555= | Silent (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- IQCA1 | c.6G>A p.S2= | Silent (SNP) | VAF 262/433 reads (61%) | called by muse, mutect2, varscan2
- ITGB4 | c.3702G>A p.T1234= | Silent (SNP) | VAF 37/552 reads (7%) | catalogued as rs753829484; called by muse, mutect2
- KIR2DL3 | c.411C>A p.P137= | Silent (SNP) | VAF 48/202 reads (24%) | catalogued as rs1423599819; called by muse, mutect2, varscan2
- KRT25 | c.807C>T p.D269= | Silent (SNP) | VAF 158/373 reads (42%) | catalogued as rs373440961; called by muse, mutect2, varscan2
- L1CAM | c.888C>G p.T296= | Silent (SNP) | VAF 296/601 reads (49%) | called by muse, mutect2, varscan2
- LCE1C | c.321C>T p.G107= | Silent (SNP) | VAF 216/468 reads (46%) | catalogued as rs551622346, COSV64218139, COSV64218259; called by muse, varscan2
- LEPR | c.1791T>C p.S597= | Silent (SNP) | VAF 24/428 reads (6%) | catalogued as rs1251229163; called by muse, mutect2
- MTMR4 | c.3336T>C p.V1112= | Silent (SNP) | VAF 11/355 reads (3%) | called by muse, mutect2
- OR2T1 | c.582C>T p.Y194= | Silent (SNP) | VAF 277/277 reads (100%) | catalogued as rs148427102; called by muse, mutect2, varscan2
- OR4K5 | c.717G>T p.T239= | Silent (SNP) | VAF 118/579 reads (20%) | catalogued as rs137857056, COSV100262301; called by muse, mutect2, varscan2
- PCNT | c.747G>A p.A249= | Silent (SNP) | VAF 132/339 reads (39%) | catalogued as rs779621529; called by muse, mutect2
- PCNX1 | c.5142A>G p.L1714= | Silent (SNP) | VAF 47/273 reads (17%) | catalogued as rs1358587443; called by muse, mutect2, varscan2
- PIK3CG | c.75G>A p.P25= | Silent (SNP) | VAF 248/667 reads (37%) | catalogued as rs1279668366, COSV63249013; called by muse, mutect2, varscan2
- PKP2 | c.837C>T p.P279= | Silent (SNP) | VAF 229/484 reads (47%) | catalogued as rs572938229; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PRR23B | c.192C>T p.A64= | Silent (SNP) | VAF 283/633 reads (45%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.2082A>G p.E694= | Silent (SNP) | VAF 75/352 reads (21%) | catalogued as rs1279696078; called by muse, mutect2, varscan2
- RHEBL1 | c.432A>G p.T144= | Silent (SNP) | VAF 58/324 reads (18%) | catalogued as rs1329625934; called by muse, mutect2, varscan2
- RPL5 | c.696T>C p.T232= | Silent (SNP) | VAF 13/228 reads (6%) | called by muse, mutect2
- SERPINA10 | c.738T>C p.F246= | Silent (SNP) | VAF 26/464 reads (6%) | catalogued as COSV100004089; called by muse, mutect2
- SLMAP | c.699A>G p.E233= | Silent (SNP) | VAF 25/208 reads (12%) | called by muse, mutect2, varscan2
- SYT16 | c.1254C>G p.V418= | Silent (SNP) | VAF 297/555 reads (54%) | catalogued as COSV70855366; called by muse, mutect2, varscan2
- TIE1 | c.3402A>T p.T1134= | Silent (SNP) | VAF 171/354 reads (48%) | called by muse, mutect2, varscan2
- TRPV6 | c.1116G>T p.L372= | Silent (SNP) | VAF 251/755 reads (33%) | called by muse, mutect2, varscan2
- TRRAP | c.195C>T p.I65= | Silent (SNP) | VAF 75/442 reads (17%) | called by muse, mutect2, varscan2
- TTN | c.93384T>C p.D31128= (on ENST00000591111; = p.D23704= on NM_003319.4) | Silent (SNP) | VAF 13/319 reads (4%) | called by muse, mutect2
- ZFC3H1 | c.999T>C p.T333= | Silent (SNP) | VAF 32/254 reads (13%) | called by muse, varscan2
- ZNF285 | c.1323A>G p.T441= | Silent (SNP) | VAF 162/272 reads (60%) | called by muse, mutect2, varscan2
- ATG13 | c.790-801A>G | Intron (SNP) | VAF 37/544 reads (7%) | called by muse, mutect2
- FGR | c.-77+370A>G | Intron (SNP) | VAF 20/396 reads (5%) | catalogued as rs1038218740; called by muse, mutect2
- IL15 | c.-165A>G | 5'UTR (SNP) | VAF 20/346 reads (6%) | called by muse, mutect2
- PBX1 | c.191+147A>G | Intron (SNP) | VAF 142/340 reads (42%) | called by muse, varscan2
- SATL1 | c.-169A>G | 5'UTR (SNP) | VAF 58/752 reads (8%) | called by muse, mutect2
- STAU1 | c.610-18T>C | Intron (SNP) | VAF 31/250 reads (12%) | called by muse, mutect2, varscan2
